Somatic mutation profile of tumor specimen TCGA-44-3917-01B (aliquot TCGA-44-3917-01B-02D-A271-08) from TCGA case TCGA-44-3917, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 33.3 years (12,179 days).
Specimen TCGA-44-3917-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff477ec3-d56f-41eb-a9b2-d384381e2143.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-3917-10A (Blood Derived Normal), aliquot TCGA-44-3917-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33d7e211-edf6-4526-baca-552aa1a6caf2

The open-access MAF lists 244 somatic variants for this specimen: 182 protein-altering or splice-affecting, 55 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 55, Nonsense Mutation 14, Splice Site 5, Frame Shift Del 4, 5'UTR 2, Intron 2, RNA 1, Splice Region 1, 3'Flank 1, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ACOT4 | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV100412783; called by muse, mutect2, varscan2
- ADAMTS14 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs1205242029, COSV100941385, COSV64605277; called by muse, mutect2, varscan2
- ADAMTS15 | c.1093C>A p.H365N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143111; called by muse, mutect2, varscan2
- ADCY6 | c.865-1G>A p.X289_splice | Splice Site (SNP) | VAF 12/76 reads (16%) | catalogued as rs1471933477, COSV100326413; called by muse, mutect2, varscan2
- ADRB2 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV100019096; called by muse, mutect2, varscan2
- AFAP1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); catalogued as rs936347149, COSV61800251; called by muse, mutect2, varscan2
- AFF3 | c.3049G>T p.A1017S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417827; called by muse, mutect2, varscan2
- AGTR1 | c.1077G>T p.E359D | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as COSV100836933; called by muse, mutect2, varscan2
- AHNAK2 | c.13079G>T p.G4360V | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.91); catalogued as COSV100315734; called by muse, mutect2, varscan2
- AHNAK2 | c.4996C>A p.P1666T | Missense Mutation (SNP) | VAF 126/489 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100315735; called by muse, mutect2, varscan2
- ALPK2 | c.4825C>T p.P1609S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV100864136; called by muse, mutect2, varscan2
- ANO4 | c.2759A>T p.E920V (on ENST00000392977 / NM_001286615.2; = p.E885V on NM_178826.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152056; called by muse, mutect2, varscan2
- APOB | c.9914C>A p.P3305Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263767; called by muse, mutect2, varscan2
- ARFGEF1 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 86/198 reads (43%) | catalogued as COSV99141127; called by muse, mutect2, varscan2
- ATP5MC1 | c.297-2A>T p.X99_splice | Splice Site (SNP) | VAF 93/255 reads (36%) | catalogued as COSV100582370; called by muse, mutect2, varscan2
- AXDND1 | c.475G>C p.G159R | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV100858252; called by muse, mutect2, varscan2
- BCKDHA | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV99524439; called by muse, mutect2, varscan2
- BMP6 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.454); catalogued as COSV99306359; called by muse, mutect2
- BTN2A2 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100760240; called by muse, mutect2, varscan2
- C9orf131 | c.741C>A p.H247Q | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV100397926; called by muse, mutect2, varscan2
- CACNA1E | c.2612G>A p.R871K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100701295; called by muse, mutect2
- CACNA1E | c.6562G>T p.G2188* (on ENST00000367573 / NM_001205293.3; = p.G2145* on NM_000721.4) | Nonsense Mutation (SNP) | VAF 11/108 reads (10%) | catalogued as COSV100701296, COSV62389009; called by muse, mutect2, varscan2
- CACNA2D1 | c.3299A>C p.H1100P (on ENST00000356253 / NM_001366867.1; = p.H1088P on NM_000722.4) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100665981; called by muse, mutect2, varscan2
- CBLL2 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100081471; called by muse, mutect2, varscan2
- CCDC144A | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100501951; called by muse, mutect2, varscan2
- CCDC150 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV99776533; called by muse, mutect2, varscan2
- CCDC190 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as COSV100905804; called by muse, mutect2, varscan2
- CCDC43 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV100188901; called by muse, mutect2, varscan2
- CD209 | c.786C>G p.F262L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as COSV52653411, COSV99213676; called by muse, mutect2, varscan2
- CD3D | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV99416471; called by muse, mutect2, varscan2
- CEP350 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100854324; called by muse, mutect2, varscan2
- CHFR | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99904976; called by muse, mutect2, varscan2
- CLMP | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV101507376; called by muse, mutect2, varscan2
- COL11A1 | c.4972G>T p.V1658L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100615262, COSV62186795; called by muse, mutect2, varscan2
- COL11A1 | c.2974C>G p.P992A | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100615263; called by muse, mutect2, varscan2
- COL12A1 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 141/288 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs370256196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs182278784, COSV64632339; ClinVar: uncertain significance; called by muse, varscan2
- COL4A6 | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858652, COSV57872087; called by muse, mutect2, varscan2
- CORO1C | c.630+1G>T p.X210_splice | Splice Site (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99775744; called by muse, mutect2
- CORO1C | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99775749; called by muse, mutect2
- COTL1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV52290024, COSV99296949; called by muse, mutect2, varscan2
- CPA4 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55985376; called by muse, mutect2, varscan2
- CPS1 | c.2073G>T p.L691F | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as COSV99242249; called by muse, mutect2, varscan2
- CSNK1G3 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100631332; called by muse, mutect2, varscan2
- CYFIP2 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV100555679; called by muse, mutect2, varscan2
- CYP4V2 | c.1467G>A p.W489* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV101114748; called by muse, mutect2, varscan2
- CYP7A1 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV100052177; called by muse, mutect2, varscan2
- DHX8 | c.2342C>G p.T781S | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99291938; called by muse, mutect2, varscan2
- DIP2B | c.4069C>T p.P1357S | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99997940; called by muse, mutect2, varscan2
- DNAH7 | c.10054G>A p.D3352N | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100413907; called by muse, mutect2, varscan2
- DNAH8 | c.7933G>C p.V2645L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV100543408; called by muse, mutect2
- DOCK10 | c.1483G>T p.V495L | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99287724; called by muse, mutect2, varscan2
- DPY19L1 | c.1081A>T p.I361F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV100204473; called by muse, mutect2, varscan2
- DZIP1 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100714009, COSV100714117; called by muse, mutect2, varscan2
- EDDM3B | c.442T>C p.*148Qext*18 | Nonstop Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100460759; called by muse, mutect2, varscan2
- EIF3E | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV55201312, COSV99622827; called by muse, varscan2
- EYS | c.863-1G>T p.X288_splice | Splice Site (SNP) | VAF 33/107 reads (31%) | catalogued as COSV100675699; called by muse, mutect2, varscan2
- F5 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100888918; called by muse, mutect2
- FAM186B | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV99217986; called by muse, mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 21/136 reads (15%) | catalogued as rs757443519; called by mutect2, varscan2
- FAT4 | c.10380G>T p.Q3460H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV58691084; called by muse, mutect2, varscan2
- FBN2 | c.4339T>C p.C1447R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99325134; called by muse, mutect2, varscan2
- FOXI2 | c.572T>C p.F191S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100510940; called by muse, mutect2, varscan2
- G6PD | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs137852337, CM920289, COSV100854937; called by muse, mutect2, varscan2
- GABRA3 | c.1282C>G p.P428A | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs374567584, COSV100942442, COSV64800051; called by muse, mutect2, varscan2
- GATAD2A | c.1835G>T p.R612L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1382309211, COSV53067733, COSV99389659; called by muse, mutect2, varscan2
- GON4L | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99673366; called by muse, mutect2, varscan2
- GPR78 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs767824059, COSV101223998, COSV66763165; called by muse, mutect2, varscan2
- GRIN2B | c.3592G>T p.E1198* | Nonsense Mutation (SNP) | VAF 38/78 reads (49%) | catalogued as rs1555102052, COSV101662917; called by muse, mutect2, varscan2
- GTPBP10 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745673; called by muse, mutect2, varscan2
- HPS1 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100282350; called by muse, mutect2, varscan2
- HUWE1 | c.7903A>T p.T2635S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99470733; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.078); catalogued as COSV56263011; called by muse, mutect2, varscan2
- ITGAX | c.1842G>T p.R614S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99191453; called by muse, mutect2, varscan2
- ITIH6 | c.2803C>A p.L935M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV99512867; called by muse, mutect2, varscan2
- KCNH5 | c.2416G>T p.G806* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as COSV100525445, COSV59777864; called by muse, mutect2, varscan2
- KCNK10 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100067089; called by muse, mutect2, varscan2
- KCNK13 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99965512; called by muse, mutect2, varscan2
- KCNS2 | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99750729; called by muse, mutect2, varscan2
- KEL | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747360606, COSV100786873; called by muse, mutect2, varscan2
- KERA | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 18/144 reads (13%) | catalogued as COSV99899316; called by muse, mutect2, varscan2
- KIF5A | c.2538G>C p.Q846H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54053525, COSV99672469; called by muse, mutect2, varscan2
- KLHL1 | c.2087G>T p.C696F | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100917022; called by muse, mutect2, varscan2
- LAMA2 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV101370109; called by muse, mutect2, varscan2
- LCP1 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100549711, COSV59942701; called by muse, mutect2, varscan2
- LECT2 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.188); catalogued as COSV99191814, COSV99191844; called by muse, mutect2, varscan2
- LGR5 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs767708854, COSV99877538; called by muse, mutect2, varscan2
- LINGO2 | c.1376G>T p.R459I | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430177; called by muse, mutect2, varscan2
- LRP1B | c.13777G>T p.G4593C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV67251368; called by muse, mutect2, varscan2
- LRP6 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99742435; called by muse, mutect2, varscan2
- MAN2A1 | c.3431G>T p.R1144M | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99810487; called by muse, mutect2, varscan2
- MCM3AP | c.3799C>T p.P1267S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199243662, COSV99386502; called by muse, mutect2, varscan2
- MCTP2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV100537224, COSV59146121; called by muse, mutect2, varscan2
- MEFV | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99560299; called by muse, mutect2, varscan2
- MLPH | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221837; called by muse, mutect2, varscan2
- MOCOS | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV99732836; called by muse, mutect2, varscan2
- MYH1 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99874971; called by muse, mutect2, varscan2
- NAV3 | c.1908-1G>T p.X636_splice | Splice Site (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99887176; called by muse, mutect2, varscan2
- NELL1 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.885); catalogued as COSV100119195, COSV54265162; called by muse, mutect2, varscan2
- NELL1 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV54290586; called by muse, mutect2, varscan2
- NIT1 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100919028; called by muse, mutect2, varscan2
- NTRK1 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.974); catalogued as rs774654606, COSV62323476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OASL | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99984428; called by muse, mutect2, varscan2
- ODF3L1 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100150699; called by muse, mutect2, varscan2
- OR11H12 | c.490T>A p.W164R | Missense Mutation (SNP) | VAF 38/452 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101612459; called by muse, mutect2
- OR1S2 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV100224025; called by muse, mutect2, varscan2
- OR2T6 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100861486; called by muse, mutect2, varscan2
- OR4C46 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as rs776942943, COSV100060417, COSV100060471; called by muse, mutect2, varscan2
- OR51V1 | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV100343238; called by muse, mutect2, varscan2
- OR52K1 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV100297585, COSV56903770; called by muse, mutect2, varscan2
- OR7G3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV59641431; called by muse, mutect2, varscan2
- OR8G5 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100422232; called by muse, varscan2
- OTOF | c.2663C>G p.T888R (on ENST00000272371 / NM_194248.3; = p.T141R on NM_004802.4) | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs766595357, COSV99716629, COSV99718786; called by muse, mutect2
- P3H1 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99354849; called by muse, mutect2, varscan2
- PAOX | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs747718413, COSV53374905, COSV99529669; called by muse, mutect2, varscan2
- PCDH11X | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100006772; called by muse, mutect2, varscan2
- PCDHA10 | c.1424C>A p.T475K | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100247807; called by muse, mutect2, varscan2
- PCDHA3 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100793171, COSV63539275; called by muse, mutect2, varscan2
- PLEC | c.7731G>C p.Q2577H (on ENST00000322810 / NM_201380.4; = p.Q2467H on NM_000445.5) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.797); catalogued as rs1554689985, COSV100511060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLTP | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99509667; called by muse, mutect2
- PLXNA2 | c.4886G>T p.G1629V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as COSV100885149; called by muse, mutect2, varscan2
- PPARD | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs766827287; called by muse, mutect2, varscan2
- PPM1F | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs763888472, COSV99601282; called by muse, mutect2, varscan2
- PRICKLE4 | c.208G>A p.G70R (on ENST00000359201; = p.G110R on NM_013397.6) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100138630; called by muse, mutect2, varscan2
- PRKDC | c.10282G>T p.E3428* | Nonsense Mutation (SNP) | VAF 44/107 reads (41%) | catalogued as COSV100038547, COSV58064282; called by muse, mutect2, varscan2
- PRKDC | c.10281G>T p.E3427D | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as COSV100038549; called by muse, mutect2, varscan2
- PTPRB | c.4484C>A p.A1495D | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99715957; called by muse, mutect2, varscan2
- PXDNL | c.2734G>T p.D912Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100681536, COSV62496219; called by muse, mutect2, varscan2
- PYGO1 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100114486; called by muse, mutect2, varscan2
- RGS22 | c.3439A>G p.M1147V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs753883129, COSV100692998; called by muse, mutect2, varscan2
- RGS22 | c.2073G>C p.K691N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100693000; called by muse, mutect2, varscan2
- RIF1 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54612602, COSV99690102; called by muse, mutect2, varscan2
- ROS1 | c.800A>T p.N267I | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100876525; called by muse, mutect2, varscan2
- RWDD2B | c.943G>C p.G315R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99725528; called by muse, mutect2, varscan2
- SLA2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.401); catalogued as COSV99481253; called by muse, mutect2
- SLC39A12 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV101069852; called by muse, mutect2, varscan2
- SLC66A3 | c.148del p.L50Wfs*15 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | catalogued as COSV54466412; called by mutect2, pindel, varscan2
- SPAG17 | c.5143C>G p.R1715G | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100308022, COSV60468652, COSV60469688; called by muse, mutect2, varscan2
- SPEG | c.4060C>T p.Q1354* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100403362; called by muse, mutect2, varscan2
- SPHKAP | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100763728; called by muse, mutect2, varscan2
- SPTA1 | c.2683C>A p.L895I | Missense Mutation (SNP) | VAF 200/363 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63759643; called by muse, mutect2, varscan2
- SULT1E1 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV56946153, COSV99894745, COSV99895327; called by muse, mutect2, varscan2
- SYCE1 | c.695G>T p.R232L (on ENST00000343131 / NM_001143764.3; = p.R196L on NM_130784.3) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100385704; called by muse, mutect2, varscan2
- SYNPO2 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100204933; called by muse, mutect2, varscan2
- TARS2 | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs964813368, COSV100945857; called by muse, mutect2, varscan2
- TAS2R1 | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1486840476, COSV101225690, COSV66778006; called by muse, mutect2, varscan2
- THOC2 | c.4201C>G p.P1401A | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99832779; called by muse, mutect2, varscan2
- THSD7B | c.2137G>T p.V713L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV99744833; called by muse, mutect2, varscan2
- TIMD4 | c.141C>A p.H47Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143159453, COSV99192499; called by muse, mutect2, varscan2
- TLR4 | c.1668A>G p.I556M (on ENST00000355622 / NM_138554.5; = p.I516M on NM_003266.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100842666; called by muse, mutect2, varscan2
- TM4SF20 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV100459972; called by muse, varscan2
- TMC5 | c.2696G>A p.R899Q (on ENST00000396229 / NM_001105248.1; = p.R653Q on NM_024780.5) | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs527274612, COSV54902690; called by muse, mutect2, varscan2
- TRIM58 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100824894; called by muse, mutect2, varscan2
- TRIML2 | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100455893; called by muse, mutect2, varscan2
- TSHR | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99991086; called by muse, mutect2, varscan2
- TSR1 | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs750993264, COSV99279761; called by muse, mutect2, varscan2
- TTI1 | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 58/140 reads (41%) | catalogued as COSV100989579; called by muse, mutect2, varscan2
- TTLL6 | c.1391G>A p.R464Q (on ENST00000393382 / NM_001130918.3; = p.R157Q on NM_173623.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.611); catalogued as rs202000811, COSV100938055, COSV100938212; called by muse, mutect2, varscan2
- TTN | c.82421A>G p.Y27474C (on ENST00000591111; = p.Y20050C on NM_003319.4) | Missense Mutation (SNP) | VAF 29/166 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV100595533; called by muse, mutect2, varscan2
- TTN | c.25286C>G p.S8429C (on ENST00000591111; = p.S7502C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | PolyPhen possibly damaging (0.767); catalogued as COSV100595535, COSV60368066; called by muse, mutect2
- TUT4 | c.2372C>G p.A791G | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV99931849; called by muse, mutect2, varscan2
- UBE4A | c.1897G>T p.G633C (on ENST00000252108 / NM_001204077.2; = p.G640C on NM_004788.4) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV99347886; called by muse, mutect2
- USH2A | c.9957A>T p.P3319= | Splice Region (SNP) | VAF 40/158 reads (25%) | catalogued as COSV100229413; called by muse, mutect2, varscan2
- USH2A | c.9662T>A p.V3221D | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100229416; called by muse, mutect2, varscan2
- USP48 | c.1572A>G p.I524M | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV100379519; called by muse, mutect2, varscan2
- VPS13C | c.4322A>T p.K1441I (on ENST00000644861 / NM_020821.3; = p.K1398I on NM_017684.5) | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV99827314; called by muse, mutect2, varscan2
- ZBTB38 | c.231C>G p.D77E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.224); catalogued as COSV100375353, COSV58541452; called by muse, mutect2, varscan2
- ZFAT | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100914258; called by muse, mutect2, varscan2
- ZFC3H1 | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs752653262, COSV101110339; called by muse, mutect2, varscan2
- ZNF280D | c.2857C>G p.Q953E | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV50996432; called by muse, mutect2, varscan2
- ZNF33B | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100847595, COSV63943424; called by muse, mutect2, varscan2
- ZP2 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs770801322, COSV99559217; called by muse, mutect2, varscan2
- ZSCAN18 | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99559108; called by muse, mutect2, varscan2
- ZSWIM2 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV99719932; called by muse, mutect2, varscan2
- ATP8B3 | c.1176del p.C393Afs*113 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- GRID2 | c.1471G>C p.A491P | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- INPP4A | c.1409C>G p.S470C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- KLHL1 | c.95del p.P32Rfs*34 | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | called by mutect2, pindel, varscan2
- OTP | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.081); called by muse, mutect2
- ROBO1 | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ARPC2 | c.504G>T p.V168= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV99826565; called by muse, mutect2, varscan2
- C1orf141 | c.735C>T p.F245= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs267598698, COSV63992364; called by muse, mutect2, varscan2
- CATSPER1 | c.1152G>A p.Q384= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV56414122; called by muse, mutect2, varscan2
- CCNQ | c.517C>T p.L173= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99367873; called by muse, mutect2, varscan2
- CDK17 | c.1164A>G p.L388= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as rs1565803499, COSV99702452; called by muse, mutect2, varscan2
- CPA4 | c.885C>A p.I295= | Silent (SNP) | VAF 99/200 reads (50%) | catalogued as COSV99744659; called by muse, mutect2, varscan2
- CSMD3 | c.10242A>T p.P3414= (on ENST00000297405 / NM_001363185.1; = p.P3245= on NM_052900.3) | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV99825576; called by muse, mutect2, varscan2
- DGKB | c.771T>C p.Y257= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as rs551396536, COSV99336635; called by muse, mutect2, varscan2
- DRD5 | c.1116G>T p.L372= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1198577668, COSV100431552; called by muse, mutect2, varscan2
- EP400 | c.7737C>T p.T2579= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100200476; called by muse, mutect2, varscan2
- FPGT | c.765G>A p.V255= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100907068; called by muse, mutect2, varscan2
- GATAD2A | c.1836C>T p.R612= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV99389664; called by muse, mutect2, varscan2
- HOXA1 | c.582C>A p.P194= | Silent (SNP) | VAF 68/193 reads (35%) | catalogued as rs751945966, COSV56065197, COSV99761011; called by muse, mutect2, varscan2
- HP | c.1215G>A p.E405= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV100577455; called by muse, mutect2, varscan2
- HPSE2 | c.1023G>A p.R341= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as rs1412598558, COSV100985045; called by muse, mutect2, varscan2
- HRNR | c.5577C>A p.G1859= | Silent (SNP) | VAF 88/1526 reads (6%) | catalogued as COSV100913003; called by muse, mutect2
- KCNA5 | c.744C>T p.S248= | Silent (SNP) | VAF 32/188 reads (17%) | catalogued as COSV52905663, COSV52905748; called by muse, mutect2, varscan2
- KCNK13 | c.1170G>C p.G390= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs749642093, COSV56414750, COSV99965513; called by muse, mutect2, varscan2
- KCNQ3 | c.921G>T p.L307= | Silent (SNP) | VAF 21/162 reads (13%) | catalogued as COSV101195656, COSV101195750; called by muse, mutect2, varscan2
- KRTAP10-8 | c.30T>C p.Y10= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as COSV100552015; called by muse, mutect2, varscan2
- LAMP5 | c.522C>T p.T174= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs780164560, COSV99855446; called by muse, mutect2, varscan2
- MAGEA4 | c.951C>A p.V317= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as COSV99367298; called by muse, mutect2, varscan2
- NEUROD6 | c.840C>T p.D280= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs780201489, COSV51772738; called by muse, mutect2, varscan2
- OR10K1 | c.273C>A p.T91= | Silent (SNP) | VAF 43/295 reads (15%) | catalogued as rs1176719574, COSV56873279; called by muse, mutect2, varscan2
- OR52I2 | c.19C>A p.R7= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100442840; called by muse, mutect2, varscan2
- OVCH1 | c.1998C>T p.A666= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV100548249; called by muse, mutect2
- PDGFC | c.792G>A p.K264= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV56856134, COSV56856213; called by muse, mutect2, varscan2
- PHEX | c.1167C>T p.F389= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV101039404; called by muse, mutect2, varscan2
- PLAU | c.393C>G p.P131= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV101032249; called by muse, mutect2, varscan2
- PLPPR4 | c.2094C>T p.H698= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- PNKD | c.729C>T p.Y243= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99282176; called by muse, mutect2, varscan2
- POLE | c.3036C>T p.Y1012= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as rs1060504062, COSV100265442; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPDPFL | c.156C>A p.S52= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV57461897; called by muse, mutect2, varscan2
- PPRC1 | c.4236C>T p.A1412= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs762078980, COSV99531322; called by muse, mutect2, varscan2
- PROX1 | c.1974C>T p.D658= | Silent (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- PRSS55 | c.114C>A p.A38= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV100153632; called by muse, varscan2
- ROBO1 | c.1956G>A p.V652= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, varscan2
- RPL19 | c.90T>C p.N30= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV99841366; called by muse, mutect2, varscan2
- RYR3 | c.8550C>T p.P2850= (on ENST00000389232; = p.P2851= on NM_001036.6) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV66803796; called by muse, mutect2
- SAMD9L | c.1023G>C p.L341= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as COSV100560343; called by muse, mutect2, varscan2
- SEMA7A | c.1572C>T p.S524= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs145844323, COSV99984588; called by muse, mutect2, varscan2
- SLA2 | c.117C>T p.A39= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99481251; called by muse, mutect2, varscan2
- SLITRK3 | c.2037C>A p.L679= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99578539; called by muse, mutect2, varscan2
- ST6GAL2 | c.189C>T p.G63= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV64527677, COSV64527700; called by muse, mutect2
- TCF20 | c.1815G>A p.G605= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV100166282; called by muse, mutect2, varscan2
- TMEM38A | c.15G>C p.S5= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- TUBA3C | c.1227G>T p.V409= | Silent (SNP) | VAF 59/149 reads (40%) | catalogued as rs1238928009, COSV101313835; called by muse, mutect2, varscan2
- UBAP2L | c.3207G>T p.P1069= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as COSV99670565; called by muse, mutect2, varscan2
- UNC13A | c.1449C>T p.G483= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as rs746066343, COSV53207525; called by muse, mutect2, varscan2
- ZBTB41 | c.969A>G p.Q323= | Silent (SNP) | VAF 49/228 reads (21%) | catalogued as COSV100962837; called by muse, mutect2, varscan2
- ZFP42 | c.258G>C p.L86= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100478639; called by muse, mutect2, varscan2
- ZNF326 | c.402A>C p.A134= | Silent (SNP) | VAF 49/176 reads (28%) | catalogued as COSV100437903; called by muse, mutect2, varscan2
- ZNF536 | c.534G>C p.R178= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100834709; called by muse, mutect2, varscan2
- ZNF699 | c.1164G>A p.E388= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100426826; called by muse, mutect2, varscan2
- ZNF781 | c.651C>G p.L217= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as rs150275573; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701114 G>A | 3'Flank (SNP) | VAF 13/70 reads (19%) | catalogued as rs181117659; called by muse, mutect2, varscan2
- CLCA3P | n.698C>A | RNA (SNP) | VAF 17/80 reads (21%) | catalogued as rs746642744; called by muse, mutect2, varscan2
- EIF4A1 | c.515-141G>A | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as rs1216931058, COSV99548741; called by muse, mutect2, varscan2
- PI4KB | c.-17del | 5'UTR (DEL) | VAF 13/56 reads (23%) | catalogued as COSV55016259; called by mutect2, pindel, varscan2
- RBAK | c.-161G>C | 5'UTR (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100806557; called by muse, mutect2, varscan2
- S1PR3 | chr9:88991026 G>C | 5'Flank (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100560874; called by muse, mutect2
- TTN | c.10360+5456C>T | Intron (SNP) | VAF 42/98 reads (43%) | catalogued as COSV100595536; called by muse, mutect2, varscan2
